Gene-level copy-number profile of tumor specimen ALCH-B2AG-TTP1-A from ALCHEMIST case ALCH-B2AG, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.7 years (24,360 days).
Specimen ALCH-B2AG-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 83d8ca4f-a8e7-42e2-b74f-b9f6086b7876.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2AG-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/b9b4a91a-56c3-4b20-bae2-bf6863f46741

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 932; copy number 1: 24,196; copy number 2: 32,404; copy number 3: 810; copy number 4: 6; copy number 5: 45.

Homozygous deletions (total copy number 0; autosomes only): 65 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:629,062–632,616, 4 genes (within-gene range 0–1): MTND1P23, MTND2P28, MTCO1P12, AC114498.2.
- chr1:120,849,674–120,914,238, 4 genes (within-gene range 0–2): AC253572.1, RNVU1-19, PPIAL4A, AC241377.3.
- chr3:130,048,143–130,055,920, 1 gene: AC083906.4.
- chr9:9,442,060–9,442,380, 1 gene (within-gene range 0–1): RN7SL5P.
- chr12:11,351,823–11,395,566, 1 gene (within-gene range 0–2): PRB1.
- chr14:106,436,415–106,461,055, 4 genes (within-gene range 0–1): AC244452.1, IGHVII-40-1, IGHV3-41, HOMER2P1.
- chr14:106,470,264–106,470,800, 1 gene (within-gene range 0–1): IGHV3-43.
- chr19:57,578,456–57,593,890, 1 gene (within-gene range 0–1): ZIK1.
- chr21:7,744,962–8,701,562, 29 genes: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2, CR381572.1.
- chr22:18,400,407–18,757,906, 18 genes: PPP1R26P3, FAM230A, AC023490.2, FAM247B, GGTLC3, Metazoa_SRP, AC023490.3, TMEM191B, PI4KAP1, AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2, PPP1R26P4, FAM230E.
- chr22:18,794,414–18,794,804, 1 gene (within-gene range 0–1): AC008132.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 45 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,345,661–149,556,361, 4 genes, copy number 5: SEC22B2P, NOTCH2NLC, AC242842.3, NBPF19.
- chr7:116,563,594–118,004,045, 40 genes, copy number 5 (within-gene range 3–5): COMETT, MET, CAPZA2, AC002543.1, Y_RNA, RNA5SP239, ST7-AS1, AC106873.5, AC106873.7, ST7, ST7-OT4, AC106873.8, AC106873.3, AC106873.2, AC106873.6, AC106873.4, AC106873.1, TPM3P1, MIR6132, ST7-AS2, AC002542.6, AC002542.2, AC002542.3, AC002542.1, AC002542.5, AC002542.4, AC006326.1, MTND4P6, MTCYBP6, WNT2, CFTR, ASZ1, ANKRD49P4, AC000111.2, CFTR-AS1, AC000111.1, AC000061.1, CTTNBP2, AC007568.1, AC003084.1.
- chr16:16,499,533–16,664,135, 1 gene, copy number 5 (within-gene range 2–5): AC136431.1.

Autosomal genes at a single copy (total copy number 1): 24,182. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
